Somatic mutation profile of tumor specimen TCGA-12-0691-01A (aliquot TCGA-12-0691-01A-01W-0348-08) from TCGA case TCGA-12-0691, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.0 years (23,019 days).
Specimen TCGA-12-0691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ea013e4-7629-43c3-ae0c-51f4416280ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0691-10A (Blood Derived Normal), aliquot TCGA-12-0691-10A-01W-0348-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a9008c6-a4f6-4893-9c12-3d798a1a0d27

The open-access MAF lists 63 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 15, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 300/385 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 36/399 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576087006, COSV100313142; called by muse, mutect2
- ADAL | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 586/698 reads (84%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV59789603; called by mutect2, varscan2
- ADAMTS18 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 292/776 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs891093965, COSV51399337; called by muse, mutect2, varscan2
- ANKRD17 | c.4243G>T p.D1415Y | Missense Mutation (SNP) | VAF 54/1576 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100429978; called by muse, mutect2
- ATP13A3 | c.2158A>G p.I720V | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs762714187, COSV99757648; called by muse, mutect2
- ATP8B4 | c.2147C>G p.A716G | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV52709915; called by muse, mutect2, varscan2
- BMP3 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV51081823; called by muse, mutect2, varscan2
- CACNB2 | c.1781C>A p.T594N (on ENST00000324631 / NM_201596.3; = p.T539N on NM_000724.4) | Missense Mutation (SNP) | VAF 125/220 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV56613338; called by muse, mutect2, varscan2
- CD209 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.011); catalogued as rs144347526, COSV52650074; called by muse, mutect2, varscan2
- CHRNB2 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as rs770557644, COSV63807766; called by muse, mutect2, varscan2
- EGFR | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51774829, COSV51792876; called by muse, mutect2, varscan2
- FAM47C | c.1787dup p.E597Gfs*28 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs1556332783; called by pindel, varscan2
- GABRB2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 162/422 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs140795978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGA4 | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62709422; called by muse, mutect2, varscan2
- GPN3 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs556729070, COSV57399037; called by muse, mutect2, varscan2
- IL12RB2 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 171/507 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52020605; called by muse, mutect2, varscan2
- KIF27 | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 101/408 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52825460; called by muse, mutect2, varscan2
- KMT2C | c.10456C>A p.Q3486K | Missense Mutation (SNP) | VAF 58/1958 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100076484; called by muse, mutect2
- MCM3AP | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1569085951, COSV52436599; called by muse, mutect2, varscan2
- MYH7 | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as COSV62516578; called by muse, mutect2, varscan2
- NXF3 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 109/159 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67702718; called by muse, mutect2, varscan2
- OR51F2 | c.980C>A p.A327D | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV59063836; called by muse, mutect2, varscan2
- P3H4 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371401688, COSV58635156; called by muse, mutect2, varscan2
- PCDHA13 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56480351, COSV56504864; called by muse, mutect2, varscan2
- PITPNM3 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs776506570, COSV52593203; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRZ1 | c.3344T>G p.I1115S | Missense Mutation (SNP) | VAF 238/872 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV66431065; called by muse, mutect2
- PTPRZ1 | c.3353T>A p.V1118D | Missense Mutation (SNP) | VAF 234/828 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV66431073; called by muse, mutect2
- RASGRF2 | c.3668C>T p.T1223M | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as rs369787079; called by muse, mutect2, varscan2
- SAMD9 | c.2380G>C p.V794L | Missense Mutation (SNP) | VAF 167/679 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV66073180; called by muse, mutect2, varscan2
- SEC61A2 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 96/397 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs773221724, COSV53650750; called by muse, mutect2, varscan2
- SELE | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.193); catalogued as rs139816972; called by muse, mutect2, varscan2
- SERPINA7 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 231/281 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV59664903; called by muse, mutect2, varscan2
- SLC13A4 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs1016190780, COSV100818961; called by muse, mutect2, varscan2
- SLC22A4 | c.437C>G p.T146S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.019); catalogued as rs760911652, COSV52356950; called by muse, mutect2, varscan2
- SLC7A3 | c.1234A>T p.I412F | Missense Mutation (SNP) | VAF 127/158 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV53226690; called by muse, mutect2, varscan2
- SLITRK6 | c.857C>G p.A286G | Missense Mutation (SNP) | VAF 194/440 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV68389458; called by muse, mutect2, varscan2
- STK24 | c.917G>A p.W306* | Nonsense Mutation (SNP) | VAF 5/101 reads (5%) | catalogued as COSV100925024; called by muse, mutect2
- STYXL2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54806817; called by muse, mutect2, varscan2
- TASP1 | c.983T>C p.I328T | Missense Mutation (SNP) | VAF 491/1189 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61811632; called by muse, mutect2, varscan2
- TLCD5 | c.648G>C p.W216C (on ENST00000375095 / NM_001198671.2; = p.W119C on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58754652; called by muse, mutect2, varscan2
- TMEM161B | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 226/877 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1561396165, COSV56929481; called by muse, mutect2, varscan2
- TREX2 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100444315; called by mutect2, varscan2
- UBQLN4 | c.1248C>A p.N416K | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64148669; called by muse, mutect2, varscan2
- YME1L1 | c.1169G>A p.R390Q (on ENST00000326799 / NM_139312.3; = p.R333Q on NM_014263.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs931137580, COSV100464186, COSV58761832; called by muse, mutect2
- ZFAND4 | c.1509G>C p.Q503H | Missense Mutation (SNP) | VAF 117/277 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV60857833; called by muse, mutect2, varscan2
- PKN2 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- AKNA | c.1758A>G p.A586= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs377034938; called by muse, mutect2, varscan2
- BRCA1 | c.4134C>T p.V1378= | Silent (SNP) | VAF 78/250 reads (31%) | catalogued as COSV58784754; called by muse, mutect2, varscan2
- COL8A1 | c.2043C>T p.N681= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99658503; called by muse, mutect2, varscan2
- FCRL3 | c.81C>T p.L27= | Silent (SNP) | VAF 85/209 reads (41%) | catalogued as rs779246023, COSV63839664; called by muse, mutect2, varscan2
- FUT1 | c.759C>T p.H253= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs753519856, COSV59567489; called by muse, mutect2, varscan2
- GNPTAB | c.3441T>C p.F1147= | Silent (SNP) | VAF 15/372 reads (4%) | catalogued as COSV100172419; called by muse, mutect2
- ITGB7 | c.162C>T p.C54= | Silent (SNP) | VAF 43/207 reads (21%) | catalogued as rs183203082, COSV57237845; called by muse, mutect2, varscan2
- OLFML2A | c.1614C>T p.D538= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs1448450449, COSV56582046; called by muse, mutect2, varscan2
- PLCZ1 | c.1698A>G p.E566= | Silent (SNP) | VAF 32/1082 reads (3%) | catalogued as COSV99857004; called by muse, mutect2
- PPEF2 | c.2070C>T p.I690= | Silent (SNP) | VAF 368/857 reads (43%) | catalogued as rs766474177, COSV54420441; called by muse, mutect2, varscan2
- PPP6R3 | c.960G>T p.L320= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV55721819; called by muse, mutect2, varscan2
- SPATA31E1 | c.1248G>T p.L416= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV57789665; called by muse, mutect2, varscan2
- TACC2 | c.1935C>T p.D645= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs372711396; called by muse, mutect2, varscan2
- UGDH | c.366G>T p.G122= | Silent (SNP) | VAF 26/444 reads (6%) | catalogued as COSV100328588; called by muse, mutect2
- ZNF556 | c.42G>T p.T14= | Silent (SNP) | VAF 33/177 reads (19%) | catalogued as COSV100298923; called by muse, mutect2, varscan2
- GABRE | c.784+1201G>T | Intron (SNP) | VAF 17/18 reads (94%) | catalogued as COSV100944380; called by muse, varscan2
